Somatic mutation profile of tumor specimen TCGA-06-0125-01A (aliquot TCGA-06-0125-01A-01D-1490-08) from TCGA case TCGA-06-0125, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.9 years (23,343 days).
Specimen TCGA-06-0125-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55f1e904-718d-4ad3-aef3-e73f2fa1c3f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0125-10A (Blood Derived Normal), aliquot TCGA-06-0125-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b55319e9-2dd7-4ef4-803f-6e2651cc5299

The open-access MAF lists 66 somatic variants for this specimen: 53 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 11, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 2, RNA 1, In Frame Ins 1, 5'Flank 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 3089/4215 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs794728708, CM010421, COSV63694898; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.1367A>G p.K456R | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV59388871; called by muse, mutect2, varscan2
- ATP6V0A4 | c.640-1G>C p.X214_splice | Splice Site (SNP) | VAF 113/346 reads (33%) | catalogued as COSV59477418; called by muse, mutect2, varscan2
- BRS3 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 33/90 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV65711160; called by muse, mutect2, varscan2
- CACNA1D | c.1538G>A p.R513H (on ENST00000350061 / NM_001128840.3; = p.R533H on NM_000720.4) | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1559570791, COSV55452065; called by muse, mutect2, varscan2
- CDYL2 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs145890469; called by muse, mutect2, varscan2
- CHAT | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 143/178 reads (80%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs200176236, COSV60319829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNNM2 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV63995722; called by muse, varscan2
- COL3A1 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs200446048; called by muse, mutect2, varscan2
- DNMT3B | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs572676072, COSV52418300; called by muse, mutect2, varscan2
- DOCK5 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs776922979, COSV52405321; called by muse, mutect2, varscan2
- DST | c.12215C>G p.S4072C (on ENST00000361203 / NM_001374722.1; = p.S1660C on NM_015548.5) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV55023756; called by muse, mutect2, varscan2
- DTD1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs745796443, COSV66280343; called by muse, mutect2, varscan2
- ECEL1 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV58813095; called by muse, mutect2, varscan2
- EMILIN1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs760975435, COSV53154989, COSV53155566; called by muse, mutect2, varscan2
- ESX1 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 199/473 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV65424685; called by muse, mutect2, varscan2
- FAM47A | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as rs1426442027, COSV60494190; called by muse, mutect2, varscan2
- FLT3 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as COSV54059336; called by muse, mutect2, varscan2
- FZD9 | c.1072T>A p.F358I | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60670663; called by muse, mutect2, varscan2
- GLRA3 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 78/193 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV56864812; called by muse, mutect2, varscan2
- GPKOW | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50243573; called by muse, mutect2, varscan2
- GPR132 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs757850974, COSV61678126; called by muse, mutect2, varscan2
- GPR65 | c.811A>T p.M271L | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV50863237; called by muse, mutect2, varscan2
- KCTD16 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs868542964, COSV72579641; called by muse, mutect2, varscan2
- KDR | c.2107del p.D703Ifs*6 | Frame Shift Del (DEL) | VAF 100/261 reads (38%) | catalogued as COSV55771303; called by mutect2, pindel, varscan2
- KIAA1210 | c.4775A>T p.H1592L | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.15); catalogued as COSV68178092; called by muse, mutect2
- KRT74 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59772334; called by muse, mutect2, varscan2
- MAGEB6 | c.971T>A p.I324N | Missense Mutation (SNP) | VAF 169/425 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66872546; called by muse, mutect2, varscan2
- MARK4 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1033007935, COSV53465457; called by muse, mutect2, varscan2
- MKRN1 | c.811T>A p.F271I | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV55437574; called by muse, mutect2, varscan2
- MUC16 | c.4498T>C p.S1500P | Missense Mutation (SNP) | VAF 156/467 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); catalogued as COSV67476699; called by muse, mutect2, varscan2
- MYH11 | c.2655G>A p.L885= | Splice Region (SNP) | VAF 72/181 reads (40%) | catalogued as rs760141485, COSV55558843; called by muse, mutect2, varscan2
- NDRG4 | c.128-1G>C p.X43_splice (on ENST00000570248 / NM_001378344.1; = p.X75_splice on NM_020465.4 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 80/199 reads (40%) | catalogued as COSV50748834; called by muse, mutect2, varscan2
- NFATC1 | c.2053C>T p.R685* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as rs1368829678, COSV53703469; called by muse, mutect2, varscan2
- OR51F1 | c.918A>T p.K306N | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV58578735; called by muse, mutect2
- P2RY13 | c.863A>G p.D288G | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.515); catalogued as COSV56385060; called by muse, mutect2, varscan2
- PLEKHG4B | c.1466G>A p.R489H (on ENST00000283426; = p.R845H on NM_052909.5) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs529537081, COSV52049819; called by muse, mutect2, varscan2
- PRR23B | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.896); catalogued as COSV61494189; called by muse, mutect2, varscan2
- PTCH1 | c.4180C>T p.R1394* | Nonsense Mutation (SNP) | VAF 62/123 reads (50%) | catalogued as rs1297685477, COSV59465625; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 91/135 reads (67%) | catalogued as rs146650273; called by pindel, varscan2
- PWWP3B | c.1603A>C p.M535L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61800471; called by muse, mutect2, varscan2
- SIGLEC8 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 26/91 reads (29%) | catalogued as rs141833256; called by muse, mutect2, varscan2
- SLC17A7 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs150211751; called by muse, mutect2, varscan2
- TCL1B | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61551811; called by muse, mutect2, varscan2
- TEAD1 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV57566780; called by muse, mutect2, varscan2
- TGM4 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as rs754139975, COSV56094811; called by muse, mutect2, varscan2
- UGT3A2 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.59); catalogued as rs138640717; called by muse, mutect2, varscan2
- XKR7 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs371180407; called by muse, mutect2, varscan2
- ZNF274 | c.1351C>T p.R451C (on ENST00000610905; = p.R346C on NM_016324.3) | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs777288675, COSV58762764; called by muse, mutect2, varscan2
- ZNF653 | c.946G>A p.G316S | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs768514644, COSV53403741; called by muse, mutect2, varscan2
- ZNF829 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs918219907, COSV66986634; called by muse, mutect2, varscan2
- SSR3 | c.252_260dup p.H86_K87insNKH | In Frame Ins (INS) | VAF 44/114 reads (39%) | called by mutect2, varscan2
- AHNAK2 | c.1014G>A p.S338= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as rs777140241, COSV60920423; called by muse, mutect2, varscan2
- ARSD | c.1353G>A p.S451= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs749735838, COSV54200862; called by muse, mutect2, varscan2
- C1S | c.1536G>A p.P512= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as rs778691266, COSV100196695, COSV61071335; called by muse, mutect2, varscan2
- C8orf58 | c.243C>T p.A81= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs752279989, COSV51515701; called by muse, mutect2, varscan2
- CD248 | c.414C>T p.G138= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs375088730; called by muse, mutect2, varscan2
- FBLN2 | c.3327G>A p.A1109= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs746614248, COSV55486933; called by muse, mutect2
- GNGT2 | c.18C>T p.S6= | Silent (SNP) | VAF 167/389 reads (43%) | catalogued as rs758509109, COSV55930112; called by muse, mutect2, varscan2
- OR5W2 | c.285T>C p.Y95= | Silent (SNP) | VAF 71/149 reads (48%) | catalogued as COSV60615005, COSV60616842; called by muse, mutect2, varscan2
- PAFAH2 | c.225G>A p.L75= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV65339760; called by muse, mutect2, varscan2
- SLC8A2 | c.711G>A p.P237= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV52640768; called by muse, mutect2, varscan2
- SRPK2 | c.1473A>G p.R491= | Silent (SNP) | VAF 56/230 reads (24%) | catalogued as COSV61960050; called by muse, mutect2, varscan2
- MIR34A | n.56_59del | RNA (DEL) | VAF 170/466 reads (36%) | called by mutect2, pindel, varscan2
- Y_RNA | chr14:50083934 C>T | 5'Flank (SNP) | VAF 8/18 reads (44%) | catalogued as rs756371556; called by muse, mutect2, varscan2
